Somatic mutation profile of tumor specimen MMRF_1642_1_BM_CD138pos (aliquot MMRF_1642_1_BM_CD138pos_T1_KBS5U_L05814) from MMRF case MMRF_1642, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,930 days).
Specimen MMRF_1642_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 023477e1-321a-4201-a881-93ae38f7690f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1642_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1642_1_PB_Whole_C3_KBS5U_L05820; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c4646f9-8501-4015-8029-c98e367e8659

The open-access MAF lists 101 somatic variants for this specimen: 45 protein-altering or splice-affecting, 8 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 25, Intron 12, Silent 8, 5'UTR 6, 5'Flank 3, Splice Region 2, Splice Site 2, Nonsense Mutation 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBP | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs749213583; called by muse, mutect2, varscan2
- BLZF1 | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as rs764427263; called by muse, mutect2, varscan2
- CCDC102B | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs752918918; called by muse, mutect2, varscan2
- COLCA2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs776644128; called by muse, mutect2, varscan2
- DEDD2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs752237952; called by muse, mutect2, varscan2
- DLK1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1186718844, COSV100375015; called by muse, mutect2, varscan2
- FANCC | c.997C>T p.L333= | Splice Region (SNP) | VAF 23/114 reads (20%) | catalogued as rs199746448; called by muse, mutect2, varscan2
- FRMD1 | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.416); catalogued as COSV99349962; called by muse, mutect2, varscan2
- FUT1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV59567734; called by muse, mutect2, varscan2
- IGHJ5 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs369944507; called by muse, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGKV1-8 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs377547522; called by muse, mutect2, varscan2
- IGLC3 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | PolyPhen benign (0.015); catalogued as rs545905935; called by muse, mutect2, varscan2
- KIAA0825 | c.3749A>G p.E1250G | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs537612345; called by muse, mutect2, varscan2
- LRIG3 | c.3214C>T p.H1072Y | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV57863928; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2174+2dup p.X725_splice | Splice Site (INS) | VAF 6/43 reads (14%) | catalogued as rs748978135; called by mutect2, pindel
- RAD54B | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs868326709, COSV60249328; called by muse, mutect2, varscan2
- SLC17A6 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs770562194; called by muse, mutect2, varscan2
- TG | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143578780, COSV55069694; called by muse, mutect2, varscan2
- TMSB4X | c.-17+1G>A | Splice Site (SNP) | VAF 23/38 reads (61%) | catalogued as COSV66081196, COSV66081636; called by muse, mutect2, varscan2
- UGT2B15 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.202); catalogued as rs576555278, COSV57735783; called by muse, mutect2, varscan2
- USH2A | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767209934, CM1410059, COSV56358108, COSV56377053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YLPM1 | c.2767A>G p.N923D | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs368741456; called by muse, mutect2, varscan2
- ZAP70 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs773287941, COSV99385641; called by muse, mutect2, varscan2
- ZNF710 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1567242218; called by muse, mutect2, varscan2
- ADGRG3 | c.732C>A p.C244* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- CEP120 | c.2860A>T p.T954S | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GBP4 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- IGHV2-70D | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.194); called by muse, varscan2
- IGHV2-70D | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGLV4-3 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- LIPI | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- MEP1B | c.1769A>C p.H590P | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); called by mutect2, varscan2
- MPDZ | c.4418T>C p.V1473A | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKAP | c.738-6C>A | Splice Region (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- OBSCN | c.16975C>T p.P5659S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- PCDH9 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPARGC1A | c.672A>C p.K224N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRPS1L1 | c.313T>C p.S105P | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RGS3 | c.293T>G p.L98W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SORBS1 | c.599C>T p.S200L (on ENST00000361941 / NM_001034954.2; = p.S168L on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNPO | c.2387A>G p.N796S (on ENST00000394243 / NM_001166208.2; = p.N552S on NM_007286.6) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.302); called by muse, mutect2
- UNC5D | c.2288G>A p.R763K | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF727 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF773 | c.907T>C p.Y303H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IMPG1 | c.231G>A p.G77= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs764169146; called by muse, mutect2, varscan2
- KCND3 | c.453C>T p.N151= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs778897221, COSV56179078; called by muse, mutect2, varscan2
- KIZ | c.1920T>G p.S640= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- LEO1 | c.303C>T p.P101= | Silent (SNP) | VAF 69/168 reads (41%) | called by muse, mutect2, varscan2
- LINGO1 | c.411C>T p.G137= | Silent (SNP) | VAF 39/219 reads (18%) | catalogued as rs567611948; called by muse, mutect2, varscan2
- NPAP1 | c.1524G>A p.K508= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- SETD5 | c.978C>T p.L326= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs781546840; called by muse, mutect2, varscan2
- SPATA5L1 | c.723G>C p.G241= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- AC116903.1 | n.109_110del | RNA (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- C4orf50 | chr4:5989719 A>G | 5'Flank (SNP) | VAF 55/181 reads (30%) | called by muse, mutect2, varscan2
- CAST | chr5:96662300 C>G | 5'Flank (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- CCDC12 | c.244+118G>A | Intron (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- CCDC149 | c.*749A>G | 3'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- CCDC32 | c.-261T>C | 5'UTR (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- CDH19 | c.*1560A>T | 3'UTR (SNP) | VAF 4/85 reads (5%) | catalogued as rs1024543889; called by muse, mutect2
- CIAPIN1 | c.*423T>C | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- CNTN3 | c.*974C>G | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- CYB5R3 | c.*1903C>G | 3'UTR (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- DMAC2L | c.-6+1546G>C | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as rs1434397282; called by muse, mutect2, varscan2
- DPH7 | c.*346T>C | 3'UTR (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- DXO | c.-6-9T>G | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- FAM210B | c.*2035G>C | 3'UTR (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- FAM83D | c.*75C>T | 3'UTR (SNP) | VAF 79/244 reads (32%) | called by muse, mutect2, varscan2
- GABRA2 | c.1059+396C>T | Intron (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- GET4 | c.*269G>A | 3'UTR (SNP) | VAF 77/310 reads (25%) | catalogued as rs749240002; called by muse, mutect2, varscan2
- HOPX | c.145-2023T>C | Intron (SNP) | VAF 15/73 reads (21%) | called by muse, varscan2
- HUS1B | c.-8G>A | 5'UTR (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- KIF21B | c.-118C>A | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- L3MBTL1 | c.1285-8del | Intron (DEL) | VAF 17/65 reads (26%) | catalogued as rs530187269; called by mutect2, pindel, varscan2
- MXD1 | c.*3771C>T | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- NEBL | c.*4597A>T | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- NIP7 | c.*49G>C | 3'UTR (SNP) | VAF 61/221 reads (28%) | catalogued as rs1366304371; called by muse, mutect2, varscan2
- NKTR | c.774-69A>T | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- NRIP1 | c.*1119G>A | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- OPRK1 | c.*2336T>A | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- OR2G6 | chr1:248522686 C>T | 3'Flank (SNP) | VAF 60/236 reads (25%) | called by muse, mutect2, varscan2
- P2RY8 | c.*738C>G | 3'UTR (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- RDH10 | c.771-694T>A | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- RNF144B | c.-52G>A | 5'UTR (SNP) | VAF 46/81 reads (57%) | called by muse, mutect2, varscan2
- RSPO3 | c.-229C>T | 5'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs1175612995; called by muse, mutect2
- SCFD2 | c.1562-35150C>A | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.*2280A>G | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62854076 A>G | 5'Flank (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- SSBP2 | c.62+90T>A | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- TFCP2L1 | c.*5279T>C | 3'UTR (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- TMEM213 | c.*1762G>A | 3'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- TMEM72 | c.*150G>A | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TRAPPC6B | c.*1174T>G | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- TRIM46 | c.*330T>C | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- TTC5 | c.*654A>G | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- TUBA1B | c.-60G>T | 5'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- TYK2 | c.2909-97C>T | Intron (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- UBR1 | c.82-5819del | Intron (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- YPEL5 | c.*159T>A | 3'UTR (SNP) | VAF 35/120 reads (29%) | called by muse, varscan2
- YPEL5 | c.*226T>C | 3'UTR (SNP) | VAF 24/102 reads (24%) | called by muse, varscan2
- ZNF583 | c.*346C>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
